Somatic mutation profile of tumor specimen TCGA-23-1029-01B (aliquot TCGA-23-1029-01B-01W-0639-09) from TCGA case TCGA-23-1029, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 46.2 years (16,889 days).
Specimen TCGA-23-1029-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de993f5f-1edd-438c-9b2c-03f010e3e156.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1029-10A (Blood Derived Normal), aliquot TCGA-23-1029-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb517019-8ed7-4bc8-ace4-d224fba617fe

The open-access MAF lists 92 somatic variants for this specimen: 69 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 22, Nonsense Mutation 6, Frame Shift Ins 2, Splice Site 2, In Frame Del 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.752T>G p.I251S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs730882027, COSV52728902, COSV52741592, COSV52816233, COSV53108676; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as rs529819396, COSV50983587; called by muse, mutect2, varscan2
- AC098582.1 | c.694T>A p.S232T | Missense Mutation (SNP) | VAF 47/66 reads (71%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1169690201, COSV52023923; called by muse, mutect2, varscan2
- ADAD1 | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 62/93 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV56646794, COSV99635412; called by muse, mutect2, varscan2
- ADAM30 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs1449359792, COSV65561966; called by muse, mutect2, varscan2
- ADGRL2 | c.2932A>G p.T978A (on ENST00000370717 / NM_001366005.1; = p.T965A on NM_012302.4) | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs774188435, COSV54684548; called by muse, mutect2, varscan2
- APCS | c.540C>G p.D180E | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV54819063; called by muse, mutect2, varscan2
- ATP1A1 | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV55190673; called by muse, mutect2
- ATRNL1 | c.2019T>G p.C673W | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100745419; called by muse, mutect2
- BRPF3 | c.293A>G p.K98R | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV60209324; called by muse, mutect2, varscan2
- CAPN13 | c.618C>A p.H206Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV54434574; called by muse, mutect2, varscan2
- CCNA1 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV55223570; called by muse, mutect2, varscan2
- CDH2 | c.2682C>G p.F894L | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52282190, COSV52293449; called by muse, mutect2, varscan2
- CDH6 | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 75/156 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54076729; called by muse, mutect2, varscan2
- CELF1 | c.1058G>A p.G353E (on ENST00000358597 / NM_001376422.1; = p.G349E on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.264); catalogued as COSV60115002; called by muse, mutect2, varscan2
- CLDN17 | c.358G>T p.G120* | Nonsense Mutation (SNP) | VAF 67/217 reads (31%) | catalogued as COSV54524417; called by muse, mutect2, varscan2
- CLVS1 | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 105/189 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV57971257, COSV57981552; called by muse, mutect2, varscan2
- CPNE9 | c.1342_1344+26del p.X448_splice | Splice Site (DEL) | VAF 28/88 reads (32%) | catalogued as COSV56069613; called by mutect2, pindel, varscan2
- CST4 | c.340A>C p.K114Q | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV54150328; called by muse, mutect2, varscan2
- DNAH3 | c.1593C>A p.Y531* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV54545463; called by muse, mutect2, varscan2
- ENTHD1 | c.550A>T p.K184* | Nonsense Mutation (SNP) | VAF 54/75 reads (72%) | catalogued as COSV57324225; called by muse, mutect2, varscan2
- FANCM | c.3557A>C p.N1186T | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV57505493; called by muse, mutect2, varscan2
- FBLN5 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs774735234, COSV50903339, COSV99969920; called by muse, mutect2, varscan2
- FMN2 | c.2516C>T p.T839I | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as rs762477896, COSV100144997; called by muse, mutect2, varscan2
- GALNTL5 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 5/132 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101217804; called by muse, mutect2
- GBP5 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 7/136 reads (5%) | catalogued as COSV100600058; called by muse, mutect2
- GDNF | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV58481205; called by muse, mutect2, varscan2
- GPR149 | c.1470T>A p.D490E | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67669440; called by muse, mutect2, varscan2
- HID1 | c.292A>C p.S98R | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV59352212; called by muse, mutect2, varscan2
- KDM4D | c.1289G>C p.S430T | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV58636090; called by muse, mutect2, varscan2
- KLHL40 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.169); catalogued as COSV55133472; called by mutect2, varscan2
- LAMA1 | c.2643C>G p.H881Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV67543204; called by muse, mutect2, varscan2
- LTA4H | c.643A>T p.I215F | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99957086; called by muse, mutect2
- MLLT10 | c.1136A>T p.D379V | Missense Mutation (SNP) | VAF 160/368 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV57002948; called by muse, mutect2, varscan2
- MTMR14 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99931295; called by muse, mutect2
- NCKAP1 | c.672G>C p.W224C | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62943118; called by muse, mutect2, varscan2
- NRSN2 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV101206801, COSV66526981; called by muse, mutect2, varscan2
- NUTM2F | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV99480100; called by muse, mutect2, varscan2
- OR8D4 | c.687C>G p.H229Q | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV58431337; called by muse, mutect2, varscan2
- PCDH10 | c.2447A>G p.N816S | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs199658438, COSV52095132; called by muse, mutect2, varscan2
- PCDHB2 | c.2329G>T p.V777F | Missense Mutation (SNP) | VAF 120/256 reads (47%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); catalogued as rs782448343, COSV50591386, COSV50597546; called by muse, mutect2, varscan2
- PCDHB4 | c.529T>A p.F177I | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV52026126; called by muse, mutect2, varscan2
- PEX5L | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as rs777297402, COSV55854927; called by muse, mutect2, varscan2
- PHLDB2 | c.1145A>G p.N382S | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as COSV67315297; called by muse, mutect2, varscan2
- PIKFYVE | c.2240C>A p.P747H | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52247840; called by muse, mutect2, varscan2
- PLEKHH2 | c.3305C>A p.S1102* | Nonsense Mutation (SNP) | VAF 14/114 reads (12%) | catalogued as COSV56759843; called by muse, mutect2, varscan2
- PRAM1 | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55316561; called by muse, mutect2, varscan2
- PRUNE1 | c.822C>A p.C274* | Nonsense Mutation (SNP) | VAF 67/160 reads (42%) | catalogued as COSV54959600; called by muse, mutect2, varscan2
- PSMD9 | c.589dup p.E197Gfs*6 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | catalogued as rs765798193; called by pindel, varscan2
- RCSD1 | c.168dup p.K57Qfs*9 | Frame Shift Ins (INS) | VAF 14/110 reads (13%) | catalogued as rs761840115; called by mutect2, varscan2
- RP1L1 | c.7113C>A p.D2371E | Missense Mutation (SNP) | VAF 112/318 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV66759255; called by muse, mutect2, varscan2
- RPL8 | c.757C>G p.Q253E | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV52798838, COSV52799823; called by muse, mutect2, varscan2
- SFN | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as rs1169884128, COSV100212812; called by muse, mutect2
- SIRT3 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV57343981; called by muse, mutect2, varscan2
- SKIV2L | c.1750T>G p.S584A | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV64813769; called by muse, mutect2, varscan2
- SLC16A7 | c.217+1G>T p.X73_splice | Splice Site (SNP) | VAF 26/60 reads (43%) | catalogued as COSV53898796; called by muse, mutect2, varscan2
- SLC35D3 | c.1052C>G p.A351G | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV59378281; called by muse, mutect2, varscan2
- SLCO1A2 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56609091; called by muse, mutect2, varscan2
- SPG21 | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV52603840; called by muse, mutect2, varscan2
- SRP72 | c.1220G>A p.G407D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV61379057; called by muse, mutect2, varscan2
- TM9SF4 | c.1810C>T p.L604F | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV54110815; called by muse, mutect2, varscan2
- TTC39C | c.1186G>C p.V396L (on ENST00000317571 / NM_001135993.2; = p.V335L on NM_153211.4) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV58218009, COSV58220277; called by muse, mutect2, varscan2
- UBR3 | c.3955G>A p.G1319R | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55858294; called by muse, mutect2, varscan2
- ZNF772 | c.1316G>T p.C439F | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58411569; called by muse, mutect2, varscan2
- HIVEP2 | c.6862_6867del p.H2288_A2289del | In Frame Del (DEL) | VAF 30/82 reads (37%) | called by mutect2, pindel, varscan2
- PGM5 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- PRAG1 | c.4201_4209del p.K1401_L1403del | In Frame Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- TEKT5 | c.548_554del p.V183Afs*37 | Frame Shift Del (DEL) | VAF 52/152 reads (34%) | called by mutect2, pindel, varscan2
- ZNF225 | c.1078del p.Y360Ifs*5 | Frame Shift Del (DEL) | VAF 101/299 reads (34%) | called by mutect2, pindel, varscan2
- ABCG8 | c.111C>T p.Y37= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV55396030; called by muse, mutect2, varscan2
- BCAS1 | c.24C>A p.P8= | Silent (SNP) | VAF 53/140 reads (38%) | catalogued as COSV65088880; called by muse, mutect2, varscan2
- CCDC86 | c.1047G>A p.Q349= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV57126212; called by muse, mutect2
- CFH | c.3498G>A p.P1166= | Silent (SNP) | VAF 49/133 reads (37%) | catalogued as rs781405059, COSV66412240; called by muse, mutect2, varscan2
- FGF10 | c.486T>C p.N162= | Silent (SNP) | VAF 123/235 reads (52%) | catalogued as COSV52938816; called by muse, mutect2, varscan2
- GPR142 | c.1125C>T p.F375= | Silent (SNP) | VAF 46/53 reads (87%) | catalogued as rs769322174, COSV59519049; called by muse, mutect2, varscan2
- ICE2 | c.2187T>C p.N729= | Silent (SNP) | VAF 112/245 reads (46%) | catalogued as COSV55033592; called by muse, mutect2, varscan2
- INTS8 | c.2403T>C p.S801= | Silent (SNP) | VAF 13/264 reads (5%) | catalogued as COSV100569261; called by muse, mutect2
- LDHAL6A | c.147C>T p.V49= | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as COSV55009197; called by muse, mutect2, varscan2
- LRRK1 | c.4302G>A p.E1434= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV52624219; called by muse, mutect2, varscan2
- MKLN1 | c.537T>A p.L179= | Silent (SNP) | VAF 66/155 reads (43%) | catalogued as COSV61762427; called by muse, mutect2, varscan2
- NCCRP1 | c.666A>T p.G222= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV59213029; called by muse, mutect2, varscan2
- NUP155 | c.3570G>A p.G1190= (on ENST00000231498 / NM_153485.3; = p.G1131= on NM_004298.4) | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV51533782; called by muse, mutect2, varscan2
- NUTM2F | c.1254A>T p.G418= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99480097; called by muse, mutect2, varscan2
- PDE6C | c.537G>T p.L179= | Silent (SNP) | VAF 175/441 reads (40%) | catalogued as rs752478645, COSV65116246, COSV65117336; called by muse, mutect2, varscan2
- PLCL1 | c.2202A>G p.P734= | Silent (SNP) | VAF 69/185 reads (37%) | catalogued as COSV70866968; called by muse, mutect2, varscan2
- RIPOR1 | c.2076C>T p.S692= (on ENST00000379312 / NM_001193522.2; = p.S688= on NM_024519.4) | Silent (SNP) | VAF 164/265 reads (62%) | catalogued as COSV50252198; called by muse, mutect2, varscan2
- RLN1 | c.123C>T p.R41= | Silent (SNP) | VAF 40/60 reads (67%) | catalogued as COSV56346922; called by muse, varscan2
- SETDB1 | c.615G>C p.L205= | Silent (SNP) | VAF 82/188 reads (44%) | catalogued as COSV54991081; called by muse, mutect2, varscan2
- SLC12A5 | c.2646C>T p.F882= (on ENST00000454036 / NM_001134771.2; = p.F859= on NM_020708.5) | Silent (SNP) | VAF 35/245 reads (14%) | catalogued as COSV54800458; called by muse, mutect2, varscan2
- STN1 | c.468C>T p.D156= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs577905006, COSV56545838; called by muse, mutect2, varscan2
- ZNF676 | c.1473C>A p.T491= (on ENST00000650058; = p.T459= on NM_001001411.3) | Silent (SNP) | VAF 89/251 reads (35%) | catalogued as COSV101236206, COSV68094644; called by muse, mutect2, varscan2
- RC3H2 | c.961-180_961-171del | Intron (DEL) | VAF 72/102 reads (71%) | called by mutect2, pindel, varscan2
